Gene-level copy-number profile of tumor specimen C3L-06912-01 from CPTAC case C3L-06912, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Alive; Tissue or organ of origin: Brain, NOS; Tumor grade: G3; Age at diagnosis: 42.3 years (15,442 days).
Specimen C3L-06912-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4b1e9878-1c16-4703-9139-18daa70085ad.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06912-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/4053c8dd-cde5-469d-95f7-6729f2a475fd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 9,976; copy number 2: 45,488; copy number 3: 3,439.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–1): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.
- chr4:68,509,441–68,670,652, 6 genes (within-gene range 0–1): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 7,120. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
